Somatic mutation profile of tumor specimen 0DJHG4 from CCDI case PBBXAT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebrum; Age at diagnosis: 9.9 years (3,612 days).
Specimen 0DJHG4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25410fb1-9cd3-482f-a95e-26a028a914d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJHE2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a189604-c3ac-40be-b9cc-72216b171abe

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, 5'UTR 3, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 153/746 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP10A | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 124/698 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as rs767644611, COSV63516289; called by muse, varscan2
- BCORL1 | c.3268C>T p.R1090* | Nonsense Mutation (SNP) | VAF 106/367 reads (29%) | catalogued as COSV54389244; called by muse, mutect2, varscan2
- CEACAM16 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs745883302; called by muse, mutect2, varscan2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- LRIT1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.105); catalogued as rs1243528196; called by muse, mutect2, varscan2
- NOTCH3 | c.5944G>A p.E1982K | Missense Mutation (SNP) | VAF 98/441 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54655028; called by muse, mutect2, varscan2
- PDGFRA | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 134/775 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57265359, COSV57275273; called by muse, mutect2, varscan2
- PPM1D | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 108/616 reads (18%) | catalogued as COSV59955747; called by muse, mutect2, varscan2
- RYR2 | c.4457A>G p.Y1486C | Missense Mutation (SNP) | VAF 58/1089 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1353376223; called by muse, mutect2
- SPTA1 | c.2223T>A p.D741E | Missense Mutation (SNP) | VAF 171/1260 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV63754812; called by muse, mutect2, varscan2
- STX1B | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs1425336336; called by muse, mutect2
- TTN | c.99650T>A p.I33217N (on ENST00000591111; = p.I25793N on NM_003319.4) | Missense Mutation (SNP) | VAF 170/743 reads (23%) | PolyPhen possibly damaging (0.837); catalogued as rs374668326; called by muse, mutect2, varscan2
- BCOR | c.4141_4147del p.G1381Tfs*10 (on ENST00000378444 / NM_001123385.2; = p.G1347Tfs*10 on NM_017745.6) | Frame Shift Del (DEL) | VAF 61/325 reads (19%) | called by mutect2, pindel, varscan2
- CMA1 | c.170G>T p.R57I | Missense Mutation (SNP) | VAF 20/716 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- ENOSF1 | c.655G>T p.G219C (on ENST00000340116 / NM_001354066.2; = p.G171C on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 185/643 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ERGIC3 | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARP8 | c.1178del p.P393Hfs*9 | Frame Shift Del (DEL) | VAF 159/945 reads (17%) | called by mutect2, pindel, varscan2
- PHF8 | c.2890C>G p.L964V (on ENST00000357988 / NM_001184896.1; = p.L928V on NM_015107.3) | Missense Mutation (SNP) | VAF 36/662 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- RBM47 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 97/602 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPRR2A | c.107G>T p.C36F | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TKTL2 | c.1741T>C p.S581P | Missense Mutation (SNP) | VAF 36/774 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2
- TRIM61 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 33/563 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TSPOAP1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 17/363 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2
- APBA3 | c.1344C>T p.N448= | Silent (SNP) | VAF 62/294 reads (21%) | catalogued as rs768846433; called by muse, mutect2, varscan2
- CYP4A22 | c.1335C>T p.H445= | Silent (SNP) | VAF 42/937 reads (4%) | catalogued as rs753957494, COSV99595347; called by muse, mutect2
- KLHL42 | c.1440A>G p.E480= | Silent (SNP) | VAF 42/654 reads (6%) | called by muse, mutect2
- MYO1H | c.108C>T p.D36= | Silent (SNP) | VAF 69/464 reads (15%) | catalogued as rs759309359, COSV60444505; called by muse, mutect2, varscan2
- RNF113A | c.549C>A p.I183= | Silent (SNP) | VAF 66/388 reads (17%) | called by muse, mutect2, varscan2
- SMC1B | c.1557A>C p.L519= | Silent (SNP) | VAF 28/626 reads (4%) | called by muse, mutect2
- CCDC179 | c.-19C>T | 5'UTR (SNP) | VAF 83/311 reads (27%) | catalogued as rs928636275; called by muse, mutect2, varscan2
- CGB8 | c.-93T>A | 5'UTR (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
- RND3 | c.239-76C>G | Intron (SNP) | VAF 17/119 reads (14%) | catalogued as COSV55725135; called by muse, mutect2, varscan2
- SLC52A1 | c.-6G>A | 5'UTR (SNP) | VAF 53/322 reads (16%) | called by muse, mutect2, varscan2
- TGDS | chr13:94596192 A>T | 5'Flank (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
